TCGA case TCGA-Y6-A8TL — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: University of Arizona. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a7045324-cb44-4b37-bbaf-641642c1d903

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 65.1 years (23,776 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; AJCC clinical T: T2a; AJCC pathologic T: T3a; AJCC pathologic N: N0; Primary gleason grade: Pattern 3; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 6.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5; Tumor level prostate: Apex; Zone of origin prostate: Peripheral zone.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 328 (initial diagnosis): Days to imaging: 328 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Days to follow up: 775 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 992 days (2.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0 ng/mL (day 775).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Y6-A8TL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-Y6-A8TL-01A-02-TSB: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-Y6-A8TL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Y6-A8TL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex.
- Stage record, Psa: PSA most recent results: 0.
- Stage record, Gleason grading: Gleason pattern primary: 3; Gleason pattern secondary: 3.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 992 days; disease-specific survival: no event (censored), 992 days; progression-free interval: no event (censored), 992 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Y6-A8TL-01A-21D-A376-01): tumor purity 0.59, ploidy 1.96, whole-genome doublings 0.
